Somatic mutation profile of tumor specimen MMRF_1793_1_BM_CD138pos (aliquot MMRF_1793_1_BM_CD138pos_T1_KBS5U_K11896) from MMRF case MMRF_1793, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.7 years (23,283 days).
Specimen MMRF_1793_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00ea278b-106c-498f-a3dc-aded1bbba4bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1793_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1793_1_PB_Whole_C2_KBS5U_K11908; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6f1e806-fe20-4f8b-b462-86f9aaf5522a

The open-access MAF lists 100 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 24, Intron 17, Silent 13, 5'UTR 4, Splice Region 4, Nonsense Mutation 2, RNA 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- FGG | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100272127; called by muse, varscan2
- FUBP1 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99627687; called by muse, varscan2
- GUCY1A1 | c.853A>C p.T285P | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99638141; called by muse, mutect2, varscan2
- H1-3 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV55097576, COSV55098560; called by muse, mutect2, varscan2
- IGHV1-69 | c.217A>C p.I73L | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs11557991; called by muse, mutect2, varscan2
- IGLV3-1 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs61731689; called by muse, mutect2, varscan2
- IGLV3-1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs549543245; called by muse, varscan2
- LEMD2 | c.244T>G p.S82A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1214579647; called by muse, varscan2
- LGALS14 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 52/139 reads (37%) | catalogued as rs763021205, COSV62373013; called by muse, mutect2
- LRFN5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs772023044, COSV53257915; called by muse, mutect2, varscan2
- MSLNL | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.146); catalogued as rs542987658, COSV99557736; called by muse, mutect2, varscan2
- OR1M1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs147905359; called by muse, mutect2
- RBP3 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.129); catalogued as rs782295621; called by muse, mutect2, varscan2
- SCN10A | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs144304164; called by muse, mutect2, varscan2
- SNTG1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769991462, COSV52435349; called by muse, mutect2
- TFPI2 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 97/285 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as COSV99746605; called by muse, mutect2, varscan2
- ZNF410 | c.1003+3A>T | Splice Region (SNP) | VAF 74/170 reads (44%) | catalogued as COSV57910504; called by muse, mutect2
- ZNF543 | c.144G>T p.L48= | Splice Region (SNP) | VAF 10/198 reads (5%) | catalogued as COSV58629532; called by muse, mutect2
- ABL1 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATG2A | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCHE | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 84/330 reads (25%) | called by muse, mutect2, varscan2
- CACNA1C | c.4830T>C p.D1610= | Splice Region (SNP) | VAF 82/187 reads (44%) | called by muse, mutect2, varscan2
- DCAF1 | c.3924G>A p.M1308I | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.7517C>T p.S2506F | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIRREL3 | c.2322G>A p.M774I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2
- LEMD2 | c.310T>A p.Y104N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.326); called by muse, varscan2
- LIFR | c.34T>A p.S12T | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH8 | c.2243T>G p.L748R | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAALADL2 | c.649T>G p.Y217D | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRP1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- OLFML3 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ROBO1 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHE | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TCERG1 | c.1399+3A>G | Splice Region (SNP) | VAF 36/55 reads (65%) | called by mutect2, varscan2
- ZEB1 | c.3052T>G p.S1018A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF219 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF410 | c.1003+1G>T p.X335_splice | Splice Site (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2
- APBA2 | c.24C>T p.S8= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs770399185, COSV68790732; called by muse, mutect2, varscan2
- CDH10 | c.411G>T p.L137= | Silent (SNP) | VAF 112/332 reads (34%) | called by muse, mutect2, varscan2
- FLG | c.906C>T p.D302= | Silent (SNP) | VAF 66/157 reads (42%) | called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- IL16 | c.456T>C p.F152= | Silent (SNP) | VAF 120/260 reads (46%) | called by muse, mutect2, varscan2
- ITPR1 | c.4950C>T p.G1650= (on ENST00000354582; = p.G1635= on NM_002222.7) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1193157886, COSV56974367; called by muse, mutect2, varscan2
- LRRC75A | c.561C>T p.S187= (on ENST00000470794 / NM_001113567.3; = p.P149S on NM_207387.4) | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- NCAM2 | c.2310G>A p.V770= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV99521749; called by muse, mutect2, varscan2
- NKX6-1 | c.402C>T p.S134= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs752076077; called by muse, mutect2, varscan2
- OLFML3 | c.858C>G p.V286= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs112248404; called by muse, mutect2, varscan2
- PATJ | c.306G>A p.S102= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs760918830, COSV57155182; called by muse, mutect2, varscan2
- TMEFF2 | c.432A>C p.G144= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- ZNF558 | c.894G>A p.G298= | Silent (SNP) | VAF 39/159 reads (25%) | called by muse, mutect2, varscan2
- AC005863.1 | n.193G>C | RNA (SNP) | VAF 32/71 reads (45%) | catalogued as rs763323372; called by muse, mutect2, varscan2
- AGAP1 | c.164-38965G>A | Intron (SNP) | VAF 34/70 reads (49%) | catalogued as rs777153821; called by muse, mutect2, varscan2
- AGPAT5 | c.*1167T>A | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- AL138930.1 | n.115+4927A>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- ANKRD52 | c.*4733C>T | 3'UTR (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
- B3GNT3 | c.-5C>T | 5'UTR (SNP) | VAF 105/152 reads (69%) | called by muse, mutect2, varscan2
- BTG3 | c.*419T>G | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96088237 G>A | 3'Flank (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- CHORDC1 | c.493-741A>G | Intron (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
- CSMD1 | c.6034+46T>C | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- CTSH | c.548+63T>A | Intron (SNP) | VAF 72/146 reads (49%) | called by muse, mutect2, varscan2
- EML2 | c.1510-186T>C | Intron (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- FRAS1 | c.*2136G>T | 3'UTR (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+235G>A | Intron (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- GDA | c.*2047A>C | 3'UTR (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- GDA | c.*2363A>C | 3'UTR (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- GRIN2A | c.*9446T>C | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- HDLBP | c.*1090G>A | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- HOXA5 | c.-39A>G | 5'UTR (SNP) | VAF 109/168 reads (65%) | called by muse, mutect2, varscan2
- HOXB3 | c.-159+1024A>G | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- HP | c.89-80G>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- IL17RA | c.*4918A>C | 3'UTR (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- IL23R | c.*273C>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as rs965631959; called by muse, mutect2
- IRX3 | c.-645G>T | 5'UTR (SNP) | VAF 80/85 reads (94%) | called by muse, mutect2, varscan2
- LINC02272 | n.294C>T | RNA (SNP) | VAF 83/339 reads (24%) | called by muse, mutect2, varscan2
- LPCAT4 | c.258-27C>T | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs373054145; called by muse, varscan2
- MCM4 | c.236-26A>G | Intron (SNP) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- MEF2B | c.-30+9C>T | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as rs1017966092; called by muse, mutect2, varscan2
- NANOS1 | c.*2913T>C | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- OLFM1 | c.*924G>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- OLFML3 | c.*477C>A | 3'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as COSV57436588; called by muse, varscan2
- PAX9 | c.*1774G>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- PCDH9 | c.*55G>A | 3'UTR (SNP) | VAF 28/56 reads (50%) | catalogued as rs1193753114, COSV60531483; called by muse, mutect2, varscan2
- PDPN | c.*1759C>A | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- PGAP4 | c.*430A>G | 3'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*4409G>A | 3'UTR (SNP) | VAF 46/142 reads (32%) | catalogued as rs1444632755; called by muse, mutect2, varscan2
- PMM1 | c.282+32C>A | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- PPP4R1 | c.1574-61G>A | Intron (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- PRTG | c.*312A>G | 3'UTR (SNP) | VAF 22/149 reads (15%) | called by muse, mutect2, varscan2
- RBFOX2 | c.663+117T>G | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- RERG | c.192+48G>T | Intron (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- RIMS2 | c.*889T>G | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- SOX4 | c.*131_*133dup | 3'UTR (INS) | VAF 30/59 reads (51%) | called by mutect2, pindel, varscan2
- TIMM17A | c.*543G>C | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- TMEM132B | c.*1415_*1438del | 3'UTR (DEL) | VAF 37/142 reads (26%) | called by mutect2, pindel, varscan2
- TMEM132D | c.*1674C>A | 3'UTR (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- TMSB4X | c.-16-47G>A | Intron (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- ZNF385D | c.-147C>T | 5'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
